Somatic mutation profile of tumor specimen ALCH-B2DX-TTP1-A (aliquot ALCH-B2DX-TTP1-A-1-0-D-A77J-36) from ALCHEMIST case ALCH-B2DX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 42.1 years (15,381 days).
Specimen ALCH-B2DX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57bff539-bb37-4693-9fd9-dcf8f0e70818.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2DX-NB1-A (Blood Derived Normal), aliquot ALCH-B2DX-NB1-A-1-0-D-A77J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2a8a13a-bcee-48df-8d8e-dec4b1ae0098

The open-access MAF lists 57 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Intron 4, Nonsense Mutation 2, Splice Site 2, 5'Flank 1, RNA 1, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 36/241 reads (15%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 39/91 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.278); catalogued as rs1306940634; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52807615, COSV52822701; called by muse, varscan2
- EDEM2 | c.188T>A p.L63H | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749984821; called by muse, mutect2
- KCNK12 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1223286089; called by muse, varscan2
- KRT8 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs1023781656, COSV53176633; called by muse, mutect2
- LY6H | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.03); catalogued as rs375749043, COSV61371687; called by muse, mutect2, varscan2
- NID2 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs370272499; called by muse, mutect2, varscan2
- PITX2 | c.776C>A p.T259K (on ENST00000354925 / NM_001204397.1; = p.T266K on NM_000325.6) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV60740875; called by mutect2, varscan2
- TBC1D10C | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781115515, COSV56703038; called by muse, varscan2
- THBS2 | c.3278G>A p.R1093Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs773112452, COSV64677487; called by muse, mutect2, varscan2
- TNK2 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs752177519, COSV57372838; called by muse, varscan2
- TRIM66 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as rs1292729322; called by muse, mutect2
- VIPR2 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs973657550; called by muse, mutect2, varscan2
- ZNF233 | c.1208A>G p.Y403C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1268454772; called by muse, mutect2, varscan2
- ADAMTS17 | c.1473+1G>A p.X491_splice | Splice Site (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- ARSL | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATL1 | c.789C>A p.N263K | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CNMD | c.577T>C p.C193R | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- HOXB6 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KBTBD11 | c.1753G>A p.A585T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.039); called by muse, varscan2
- KCNJ4 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAMA1 | c.7660A>C p.I2554L | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MGA | c.6672dup p.L2225Tfs*8 (on ENST00000219905 / NM_001164273.1; = p.L2016Tfs*8 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | called by mutect2, pindel, varscan2
- MIF4GD | c.618del p.W206* (on ENST00000325102 / NM_001370592.1; = p.W240* on NM_020679.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 55/127 reads (43%) | called by mutect2, pindel, varscan2
- OR56B4 | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PCNX1 | c.5767G>T p.E1923* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2, varscan2
- PIK3CA | c.955A>T p.N319Y | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- POSTN | c.1393-2A>T p.X465_splice | Splice Site (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- PRKDC | c.1205C>A p.T402N | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.359); called by muse, mutect2
- PTPRN2 | c.2617G>A p.V873M | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RET | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- RICTOR | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- RUSC2 | c.2891C>G p.P964R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- UBLCP1 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- ZNF532 | c.1066C>G p.P356A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ABCC2 | c.4344C>A p.G1448= | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- ANK2 | c.2559A>T p.T853= | Silent (SNP) | VAF 33/118 reads (28%) | called by muse, mutect2, varscan2
- COL6A1 | c.78G>A p.P26= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- DPEP2 | c.684C>T p.G228= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs538188973; called by muse, mutect2, varscan2
- FCMR | c.774C>G p.T258= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- FGFR4 | c.954G>C p.L318= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- FRS3 | c.1146C>T p.S382= | Silent (SNP) | VAF 14/221 reads (6%) | called by muse, mutect2
- MMP3 | c.408A>G p.K136= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as rs1555005703; called by muse, mutect2, varscan2
- MYO3A | c.1698C>T p.D566= | Silent (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- NOS2 | c.1692C>T p.A564= | Silent (SNP) | VAF 8/52 reads (15%) | called by mutect2, varscan2
- SLIT2 | c.2118C>A p.A706= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99883308; called by muse, mutect2, varscan2
- STK40 | c.1074G>A p.A358= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs76939556, COSV100828617; called by muse, mutect2, varscan2
- TAS2R20 | c.835C>T p.L279= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.62+5359C>T | Intron (SNP) | VAF 15/131 reads (11%) | catalogued as rs769633559; called by muse, mutect2, varscan2
- ANAPC1P2 | n.314G>C | RNA (SNP) | VAF 26/302 reads (9%) | catalogued as rs759870734; called by muse, mutect2
- LINC01098 | n.518+19del | Intron (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- MOB3C | c.-50-1627G>T | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as COSV54720590; called by mutect2, varscan2
- PNLDC1 | c.*1G>A | 3'UTR (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- PRDM16 | chr1:3069201 A>G | 5'Flank (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- TTN | c.10303+1335T>C | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, varscan2
